Gene-level copy-number profile of tumor specimen TCGA-26-5133-01A from TCGA case TCGA-26-5133, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,560 days).
Specimen TCGA-26-5133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.14f65f72-3b03-4840-bff3-dcd6f9de1761.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-26-5133-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62083af1-6838-4602-b311-4a460b92e971

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,866; copy number 2: 43,274; copy number 3: 495; copy number 4: 103; copy number 5: 55; copy number 6: 1; copy number 8: 12; copy number 9: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-26-5133-01A-01D-1479-01): tumor purity 0.89, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,668,684–16,666,331, 24 genes, copy number 8–9: AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA.
- chr2:21,317,660–21,561,313, 1 gene, copy number 5 (within-gene range 2–5): AC011752.1.
- chr2:21,607,465–21,649,572, 2 genes, copy number 5: AC009411.2, AC009411.1.
- chr2:103,623,630–103,623,830, 1 gene, copy number 6: CAPZBP1.
- chr2:178,092,503–178,142,651, 4 genes, copy number 5: CYCTP, AC011998.1, RBM45, RNU5E-9P.
- chr8:127,253,213–130,655,712, 48 genes, copy number 5: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.

Autosomal genes at a single copy (total copy number 1): 13,485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
